Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-B0CR, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-B0CR-TTP1-A (Primary Tumor).

[page 1 of 25]
Results

PATHOLOGY (

Collection Information

Specimen ID: 1
Collected: [REDACTED] +35
Specimen ID: 2
Collected: [REDACTED] +35
Specimen ID: 3
Collected: [REDACTED] +35
Specimen ID: 4
Collected: [REDACTED] +35

Specimen Type
Tissue [117]

Specimen Source
Lymph node [376]

[REDACTED] +39

Component Results

Component
PATHOLOGY/CYTOLOGY REPORT (Final)

Patient:
MRN: [REDACTED]

Acen No:
Collected [REDACTED]

+35

SURGICAL PATHOLOGY FINAL REPORT

Diagnosis:

- A. Lymph node, Station [REDACTED] biopsy
- metastatic adenocarcinoma consistent with colonic primary.
/
- B. Lymph node, Station [REDACTED] biopsy
- metastatic adenocarcinoma consistent with colonic primary.
/
- C. Lymph node, Station [REDACTED] biopsy
- metastatic adenocarcinoma consistent with colonic primary.
/
- D. Lymph node, Station [REDACTED] biopsy
- metastatic adenocarcinoma consistent with colonic primary.

[REDACTED]
Pathologist Comment

[page 2 of 25]
Immunostains on specimen A1 are positive for CK20 and negative for CK7.

Clinical Information

History of colon cancer.

Specimen Source

- A Lymph Node, STATION [REDACTED]
- B Lymph Node, STATION [REDACTED]
- C Lymph Node, STATION [REDACTED]
- D Lymph Node, STATION [REDACTED]

Microscopic Description

Microscopic examination was performed.

Gross Description

Part A. Received in a container of formalin labelled [REDACTED] Station [REDACTED] is an aggregate of reddish-tan needle core biopsy and fragments measuring 1.5 x 0.5 x 0.2 cm. The tissue is submitted entirely in A1.

Part B. Received in a rocket tube of formalin labelled [REDACTED] Station [REDACTED] is an aggregate of reddish-tan needle core biopsy fragments and clotted blood measuring 2 x 0.6 x 0.2 cm. The specimen is submitted entirely in B1.

Part C. Received in a rocket tube of formalin labelled [REDACTED] Station [REDACTED] is an aggregate of clotted blood and needle core biopsy fragments measuring 0.5 x 0.3 x 0.2 cm. The specimen is submitted entirely in C1.

Part D. Received in a rocket tube of formalin labelled [REDACTED] Station [REDACTED] is an aggregate of pale tan pink needle core biopsies and fragments measuring 2 x 1.5 x 0.2 cm. The tissue is submitted entirely in D1.

SURGICAL PATHOLOGY PRELIMINARY REPORT

Specimen Source

Lymph nodes

Preliminary Diagnosis/Comment

Metastatic adenocarcinoma consistent with colonic primary in all biopsies. Immunohistochemical stains pending.

Lab and Collection

PATHOLOGY (Order [REDACTED])

Lab and Collection Information

Result History

+35

PATHOLOGY (Order [REDACTED])

Order Result History Report

+39

Result Entry Info

User

Result Time

Resulted From

[page 3 of 25]
Results

Laboratory Information

Lab - Abbreviation	Name	Director	Address	Valid Date Range
--------------------	------	----------	---------	------------------

Result Information

Status	Provider Status
Edited Result - FINAL (Collected: +35)	Reviewed

PATHOLOGY

Order

PATHOLOGY [LAB] (Order

Order Information

Date and Time	+35	Ordering Department	Order Placed By/Authorizing
---------------	-----	---------------------	-----------------------------

Order Providers

Authorizing

Verbal Order Info

Action	Created on	Order Mode	Entered by	Responsible Provider	Signed by	Signed on
--------	------------	------------	------------	----------------------	-----------	-----------

Original Order

Ordered On	Ordered By	Order #
------------	------------	---------

Release Information

Released On	Released By
-------------	-------------

Order Details

Frequency	Duration	Priority	Order Class
None	1 occurrence	ROUTINE	Unit Collect

Comments

Additional Information

Associated Reports
View Encounter
Priority and Order Details

[page 4 of 25]
Collection Information

Order Requisition

PATHOLOGY (

PATHOLOGY

Specimens

ID	Source	Type	Tests	Order ID	Collected by	Collected At	Frozen?	Priority?
1	Lymph node	Tissue	• PATHOLOGY				+35	
	Description: station							
2	Lymph node	Tissue	• PATHOLOGY				+35	
	Description: station							
3	Lymph node	Tissue	• PATHOLOGY				+35	
	Description: station							
4	Lymph node	Tissue	• PATHOLOGY				+35	
	Description: station							

Acknowledgement Info

For At Acknowledged By Acknowledged On

Order History

Inpatient

Date/Time	Action Taken	User	Additional Information
			From Order: Final
			Final-Edited

Order Tracking

View Order Tracking

[page 5 of 25]
Results

PATHOLOGY (Ord

Collection Information

Specimen ID: B

Collected: [REDACTED] +0

Specimen ID: A

Collected: [REDACTED] +0

Specimen Type

Tissue [117]

Specimen Source:

Gallbladder [309]

[REDACTED] +29

Component Results

Component

PATHOLOGY/CYTOLOGY REPORT (Final)

Acqn No: [REDACTED]

Collected: [REDACTED]

+0

SURGICAL PATHOLOGY FINAL REPORT

Diagnosis

A. Colon, right, hemicolectomy
- adenocarcinoma, poorly differentiated (grade 3)
- tumor is located in the cecum, measures 6 cm in greatest dimension,
and
shows invasion into the pericolic adipose tissue (pT3)
- margins are free of involvement by primary tumor
- extensive lymphatic invasion present
- metastatic adenocarcinoma is identified in sixteen out of sixteen
(16/16)
mesenteric lymph nodes (pN2b), with three additional apparently
extranodal
mesenteric tumor implants also present
- attached portion of omentum contains three grossly visible nodules
of

[page 6 of 25]
metastatic adenocarcinoma, measuring up to 4.4 cm in size (pM1)
- appendix shows no diagnostic abnormality
- see diagnostic summary below.

/

B. Gallbladder, cholecystectomy
- chronic cholecystitis
- cholelithiasis.

DIAGNOSTIC SUMMARY - COLON/RECTUM (RESECTION)

Specimen: right colon/terminal ileum

Procedure: hemicolectomy

Specimen Length: 35 cm (includes 8.5 cm of ileum)

Tumor Site: cecum

Tumor Size (greatest dimension): 6 cm

Macroscopic Tumor Perforation: absent

Histologic Type: adenocarcinoma

Histologic Grade: high grade (poorly differentiated, grade 3/4)

Microscopic Tumor Extension: into the pericolic fat

Distances to Margins:

Proximal: 10 cm

Distal: greater than 15 cm

Circumferential (Radial) or Mesenteric: 6.5 cm

Treatment Effect (if applicable): N/A

Lymph-Vascular Invasion: present (massive lymphatic involvement)

Perineural Invasion: not identified

Tumor Deposits (discontinuous extramural extension): present (three deposits identified, measuring up to 6 mm)

PATHOLOGIC STAGING

Primary Tumor: pT3

Regional Lymph Nodes: pN2b

Number examined: 16

Number involved: 16

Distant Metastasis: pM1 (colonic metastases)

Clinical Information

Colon cancer, metastatic to liver, retroperitoneal adenopathy, gallstones.

Specimen Source

A Colon, RIGHT

B Gallbladder

Microscopic Description

Microscopic examination was performed.

Gross Description

Part A. Received in a container of formalin labelled "right hemicolectomy" is a segment of right colon with terminal ileum measuring 35 cm in length. The terminal ileum segment measures 8.5 cm in length.

[page 7 of 25]
A grossly normal appearing appendix is attached to the cecum measuring 3.5 cm in length and 0.4 cm in diameter. A portion of omental fat is attached to the colon measuring 21 x 9.5 cm. Three large metastatic tumor implants are seen in this omental fat. The largest metastasis measures 4.4 cm. The colon is opened revealing an ulcerated tumor mass in the cecal pouch measuring 6 x 4 cm. The tumor involves the ileocecal valve. The tumor is located approximately 10 cm from the proximal mucosal resection margin and greater than 15 cm from the distal mucosal resection margin. In the area of the tumor the cecum has a circumference of 8.5 cm. The tumor comprises greater than 75% of the overall circumference. On sectioning the tumor appears to involve the full thickness of the colon wall extending into the pericolic fat. The radial soft tissue margin of the cecum overlying the tumor measures 6.5 cm. No additional mass lesions are identified on the mucosal surface.

Cassette Summary:

- A1 - appendix
- A2 - proximal mucosal resection margin
- A3 - distal mucosal resection margin
- A4-A7 - sections of tumor
- A8 - normal appearing colon
- A9-A10 - omental metastasis
- A11-A15 - lymph nodes.

Part B. Received in a container of formalin labelled "gallbladder" is a gallbladder measuring 9.5 cm in length and 3.5 cm in diameter. The

gallbladder is opened revealing greater than twenty black multifaceted calculi measuring up to 0.3 cm in diameter. The gallbladder wall measures 0.3 cm in thickness. The lining of the gallbladder shows intact mucosa. Representative sections of the gallbladder wall and the cystic duct are submitted in B1.

SURGICAL PATHOLOGY ADDENDUM REPORT

Discussion

[page 8 of 25]
[REDACTED] +22
On [REDACTED] pathologist examined previously stored surgical tissue
and selected block A6 which contains appropriate tumor for molecular
studies/gene mutation analysis, as ordered by [REDACTED]
The case was submitted to [REDACTED] for KRAS.

Diagnosis

RESULTS:

KRAS Status: Wild-type (negative for mutation)

See full report scanned in chart.

NOTE: Ancillary laboratory reports are scanned to the patient's
electronic health record. To view in Epic, click "Scan" located under "Results"
header immediately following this pathology report.

Scans on Order [REDACTED] +28

Lab and Collection

PATHOLOGY (Order [REDACTED]) Lab and Collection Information
+0

Result History

PATHOLOGY (Order [REDACTED]) Order Result History Report
+29

Result Entry Info

User	Result Time	Resulted From
[REDACTED]	[REDACTED]	Interfaces [101]

+29

Laboratory Information

Lab - Abbreviation	Name	Director	Address	Valid Date Range
[REDACTED]				

Result Information

Status	Provider Status
Edited Result - FINAL (Collected: [REDACTED])	Reviewed

+0

[page 9 of 25]
CBC WITH DIFFERENTIAL Final result
COMPREHENSIVE METABOLIC PANEL Edited Result -
FINAL
CBC WITH DIFFERENTIAL Final result
COMPREHENSIVE METABOLIC PANEL Edited Result -
FINAL
POC GLUCOSE Final result

+2
+2
+1
+1

Result Components

PATHOLOGY

+0

Order

PATHOLOGY

Order Information

Date and Time

+0

Ordering Department

Order Placed
By/Authorizing

Order Providers

Authorizing

Verbal Order Info

Original Order

Release Information

Order Details

Frequency
None

Duration
1 occurrence

Priority
ROUTINE

Order Class
Unit Collect

Comments

Additional Information

Associated Reports
View Encounter
Priority and Order Details

[page 10 of 25]
Collection Information

Order Requisition

PATHOLOGY (Order

PATHOLOGY (Order

+0

ID	Source	Type	Tests	Order ID	Collected by	Collected At	Frozen?	Priority?
----	--------	------	-------	----------	--------------	--------------	---------	-----------

A	Colon	Tissue	• PATHOLOGY					+0
---	-------	--------	-------------	--	--	--	--	----

Description: Right Hemicolectomy DX: Colon cancer, metastatic to liver

B	Gallbladder	Tissue	• PATHOLOGY					+0
---	-------------	--------	-------------	--	--	--	--	----

Description: DX: intraepithelial adenopathy and gallstones

Requisition Comments

Scans on Order

Scan on KRAS Results

Acknowledgement Info +28

For	At	Acknowledged By	Acknowledged On
-----	----	-----------------	-----------------

Placing Order

Placing Order

Order History

Inpatient

Date/Time	Action Taken	User	Additional Information
-----------	--------------	------	------------------------

Release

Result

Result

Order Tracking

View Order Tracking

[page 11 of 25]
IMAGING SERVICES

Exam Date/Time: [REDACTED] -27	Phone #: [REDACTED]
Sex: [REDACTED]	Account #: [REDACTED]
Malc: [REDACTED]	Performing Department: [REDACTED]
Accession #: [REDACTED]	Authorizing Provider: [REDACTED]
Pt. Class: [REDACTED]	
Outpatient: [REDACTED]	
Primary Care Provider: [REDACTED]	Ordering Provider: [REDACTED]

Final - CT ABDOMEN PELVIS W CONTRAST [REDACTED]

Reason for Exam: Other - Please see comments - Colon cecal mass

Diagnosis:

INTERPRETATION

Exam: CT ABDOMEN PELVIS W CONTRAST

Date/Time of Exam: [REDACTED] -27

Reason For Exam: Colonic mass. Cecal mass.

Helical axial images of the abdomen and pelvis were obtained during IV administration of 125 mL Optiray-240. The patient ingested oral contrast for the exam. Sagittal and coronal reformats generated.

Findings:

Lung window images demonstrate a tiny 4 mm noncalcified nodular density along the medial margin of the inferior lingula at the pleural surface. There also are very subtle reticulonodular densities in the posterior right lung base. These findings are nonspecific and could represent old granulomatous disease versus developing more significant pulmonary nodules. There is a calcified granulomatous nodule in subpleural location in the lateral right lung base. The lung bases are clear of acute infiltrates. There is a very small left pleural effusion positioned dependently in the posterior inferior left hemithorax. The heart is normal in size and shape.

Multiple worrisome appearing low density lesions are scattered throughout both lobes of the liver suspicious for hepatic metastatic disease. The largest lesion is in the medial inferior right lobe of measuring 3 cm in size. The spleen is normal in appearance. The right adrenal gland has a normal appearance. There is a nonspecific 1.5 cm nodule in the left adrenal gland. Possible adenoma versus metastatic focus. The pancreas is unremarkable. There is a punctate nonobstructing calculus in a lower pole infundibulum of the left kidney. No signs of hydronephrosis. No suspicious renal mass. Enlarged lymph nodes are seen about the margins of the aorta and inferior vena cava suspicious for potential early developing metastatic lymphadenopathy. The abdominal aorta is calcified and ectatic with greatest transverse diameter being 2.7 cm in the infrarenal segment. Small calculi are identified in the lumen of the gallbladder. No acute thickening of the gallbladder wall.

[page 12 of 25]
There is a bulky soft tissue density mass involving the cecum and most proximal ascending segments of the colon. This is suspicious for a neoplasm of the colon. Soft tissue density nodules are identified in the anterior peritoneal fat over the anterior lateral right abdomen suspicious for metastatic foci in the peritoneum.

No signs of abnormal distention of the stomach or bowel. No free air. No ascites.

Scans continuing into the pelvis demonstrate diffuse thickening of the urinary bladder wall without evidence of a focal mass. The seminal vesicles and prostate gland are grossly unremarkable. No iliac lymphadenopathy identified.

Bone window images reveal no lytic or blastic destructive changes in the visualized skeletal structures.

CT abdomen impression:

1. Large soft tissue density mass involving the cecum and proximal ascending segments of the colon compatible with carcinoma of the colon.
2. Multiple low-density lesions in the liver compatible with hepatic metastatic disease.
3. Very tiny reticulonodular densities in the posterolateral right lung base and one tiny noncalcified nodule is seen in the base of the lingula that could be related to old granulomatous disease but followup over time will be necessary if early developing pulmonary metastatic disease is to be excluded.
4. Small 1.5 cm soft tissue density nodule in the left adrenal gland that could represent a metastatic nodule there.
5. Enlarged lymph nodes in the periaortic and pericaval regions of the retroperitoneum worrisome for metastatic lymphadenopathy.
6. Focal soft tissue density nodules in the peritoneum of the right upper quadrant abdomen suspicious for peritoneal metastases. No obvious ascites.
7. Cholelithiasis.
8. Atherosclerosis of the aorta and iliac arteries with very mild aneurysmal dilatation of the abdominal aorta to a maximum diameter of 2.7 cm.

CT pelvis impression:

1. Diffuse thickening of the urinary bladder wall. This may be related to underdistention at the time of imaging or changes of chronic cystitis.
2. No mass or adenopathy identified in the pelvis.

[page 13 of 25]
IMAGING SERVICES

Exam Date/Time:	+475	Phone #:	MIN. E
Sex:	Male	Account #:	
Acquisition #:		Performing Department:	
Pt Class:	Outpatient		
Primary Care Provider:			

Final - CT ABDOMEN PELVIS W CONTRAST

Reason for Exam:

Diagnosis: Cecum cancer
Thrombocytopenia

INTERPRETATION

Exam: CT ABDOMEN PELVIS W CONTRAST

Date/Time of Exam: +475

Reason For Exam: Cecum cancer, thrombocytopenia. Malignant neoplasm of the colon. Colon cancer metastasized to liver status post right colectomy, cholecystectomy, partial omentectomy. Posttreatment follow-up to assess for metastatic disease.

Helical axial images of the abdomen and pelvis were obtained during IV administration of 100 mL Optiray 240. The patient ingested oral contrast for the exam. Sagittal and coronal reformats generated. Comparison is made with the examination of +275

Findings: Lung window images demonstrate a small calcified granulomatous nodule in the subpleural posterolateral right lung base. No suspicious nodules are seen in the lung bases. Mild parenchymal scarring is present in the inferior most lingula and left lung base. There is a calcified granulomatous nodule in the left lung base as well. The inferior pleural spaces are clear. Atherosclerotic calcifications are present in the aorta and coronary arteries. The heart is normal in size and shape. No signs of a pericardial effusion.

There is a stable 8 mm low-density lesion in the superior segment of the right lobe of the liver possibly due to a small cyst or hemangioma there. No suspicious hepatic mass lesion is identified. The gallbladder has been resected. No biliary ductal dilatation. The spleen has normal features. The pancreas has normal features. There is mild nodular thickening of the limbs of the left adrenal gland that appear stable and probably related to nodular hyperplasia. The right adrenal gland appears normal. The kidneys have normal features. No lymphadenopathy is seen in the abdomen or retroperitoneum. The abdominal aorta is diffusely ectatic and calcified as are the iliac arteries. Abundant atheromatous plaque and peripheral thrombus is present in the infrarenal aorta and iliac arteries. The abdominal aorta measures 2.6 cm in diameter just above the aortic bifurcation.

There are postoperative changes of right hemicolectomy with ileocolic

[page 14 of 25]
anastomosis over the anterior midline abdomen. No signs of abnormal distention of the stomach or bowel. No obvious acute inflammatory changes of the bowel. No obvious mass identified.

Scans continuing into the pelvis demonstrate grossly normal features of the urinary bladder. There is mild enlargement of the seminal vesicles and prostate gland. No pelvic mass or adenopathy is evident. No pelvic fluid collections. No inguinal hernia defects.

Bone window images demonstrate no lytic or blastic destructive changes in the visualized skeletal structures.

IMPRESSION

CT abdomen impression:

1. No obvious signs of metastatic disease identified in the upper abdomen or upper retroperitoneum.
2. Stable 8 mm low-density lesion in the superior right lobe of the liver probably related to an underlying cyst or meningioma.
3. No metastatic lymphadenopathy identified in the abdomen or retroperitoneum.
4. Status post cholecystectomy.
5. Status post right hemicolectomy. No obvious recurrent colonic mass or acute abnormality in the GI tract detected.
6. Advanced atherosclerosis of the abdominal aorta with 2.5 cm infrarenal abdominal aortic aneurysm.

CT pelvis impression:

1. No metastatic disease identified in the pelvis.
2. No acute process identified in the pelvis.
3. No visualized osseous metastatic foci on the exam.
-
-
-
-

[page 15 of 25]
IMAGING SERVICES

Exam Date/Time:

+480

Sex:

Male

Pt. Class:

Outpatient

Accession #:

Performing Department:

Primary Care Provider:

Final - CT CHEST W CONTRAST

Reason for Exam:

Diagnosis: Cancer

INTERPRETATION

Exam: CT CHEST W CONTRAST

Date/Time of Exam: +480

Reason For Exam: Malignant neoplasm of the colon. Thrombocytopenia.

Helical axial images of the chest were obtained during IV administration of 125 mL Optiray 240. Sagittal and coronal reformats generated.

Findings:

Lung window images demonstrate the trachea and bronchi to be patent. Some linear parenchymal scarring is present in both lung bases, greater in the left lung base. Old granulomatous calcification is present in both lower lobes. No suspicious pulmonary nodule or mass lesion is identified. No sign of a pleural effusion or pneumothorax.

Mediastinal window images demonstrate no evidence of a mediastinal mass or mediastinal lymphadenopathy. Stable shotty appearing lymph nodes are present throughout the mediastinum. The thoracic aorta is ectatic and mildly calcified. There are coronary artery calcifications. The heart is at the upper limits of normal for size. No pericardial effusion.

Bone window images reveal no lytic or blastic destructive changes in the visualized skeletal structures of the thorax.

IMPRESSION

IMPRESSION:

1. There do not appear to be signs of metastatic disease in the chest. No suspicious pulmonary nodule/mass or tumoral adenopathy.
2. No sign of acute pulmonary disease. Mild parenchymal scarring in the lung bases.
3. Atherosclerotic change of the thoracic aorta and coronary arteries.

[page 16 of 25]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[page 17 of 25]
IMAGING SERVICES

Exam Date/Time:

+630

Sex:

Male

Accession #:

Pt. Class:

Outpatient

Primary Care Provider:

Final - CT CHEST ABDOMEN PELVIS W CONT

Reason for Exam:

Diagnosis: Cecum cancer

INTERPRETATION

Exam: CT CHEST ABDOMEN PELVIS W CONT

Date/Time of Exam: +630

Reason For Exam: Cecum cancer. Malignant neoplasm of the colon. Post treatment follow-up. Repeat staging and reassessment for metastatic disease. Assessment for response to therapy.

Helical axial images of the chest, abdomen, and pelvis were obtained during IV administration of 125 mL Optiray 240. The patient ingested oral contrast for the exam. Sagittal and coronal reformats generated. Comparison made with the examination of +281 and +480

Findings:

Lung window images demonstrate the lungs to be clear of acute infiltrates. Mild interstitial scarring is present in the inferior lungs near the lung bases. Old granulomatous calcifications are present in both lung bases. No focal pulmonary mass is identified. No sign of a pleural effusion or pneumothorax.

Mediastinal window images demonstrate a right jugular Infuse-a-Port catheter coursing to the SVC. Since the examinations of +281 and +480 there has been development of enlargement of mediastinal lymph nodes located in the aortopulmonary window region, pretracheal region, precarinal region, subcarinal region, and both hilar regions, especially in the right pulmonary hilus. The findings are suspicious for developing tumoral adenopathy in the mediastinum. The thoracic aorta is mildly ectatic and calcified without segmental aneurysm or dissection. The pulmonary arterial segments appear normal in caliber and enhance. The heart is normal in size and shape. No pericardial mass or effusion. There are coronary artery calcifications. No axillary adenopathy.

Narrow liver window images demonstrate hypodense lesions in the superior right lobe of the liver, medial segment of the left lobe of

[page 18 of 25]
the liver, and very inferior posterior tip of the right lobe of the liver suspicious for hepatic metastatic disease. This appears to be new. The spleen is normal in size and shape. The pancreas is unremarkable. The right adrenal gland has normal appearance. There is nodular thickening of the limbs of the left adrenal gland. This could be related to very early metastatic disease in the left adrenal gland. No focal mass lesions are identified in the kidneys. No signs of hydronephrosis. There is a punctate nonobstructing calculus in the lower pole infundibulum of the right kidney. Lymphadenopathy is developing in the periaortic and pericaaval region of the retroperitoneum. Additional lymphadenopathy is seen in the root of the small bowel mesentery. These findings appear to be new. There are no signs of abnormal distention of the stomach or bowel. There appear to be postoperative changes of right hemicolectomy with ileocolic anastomosis over the anterior mid abdomen at the mid transverse colon. No anterior abdominal wall hernia defects.

There is atherosclerotic calcification throughout the abdominal aorta and iliac arteries. The infrarenal aortic segment shows mild aneurysmal dilatation to a maximum diameter of 3 cm. There is diffuse aneurysmal dilatation of the left common iliac artery to a diameter of 2 cm. The right common iliac artery is ectatic measuring 1.7 cm. No retroperitoneal hematoma.

Scans continuing into the pelvis demonstrate grossly normal features of urinary bladder. The seminal vesicles are unremarkable. There is mild generalized enlargement of the prostate gland mildly impressing upon the base of the urinary bladder. No discrete pelvic mass. No pelvic lymphadenopathy. No pelvic fluid collections. The pelvic bowel is without signs of inflammation. There is a small right inguinal hernia defect containing only fat.

Bone window images reveal no lytic or blastic destructive changes in the visualized skeletal structures. Degenerative arthritic changes are present throughout the thoracolumbar spine.

IMPRESSION

CT chest impression:

1. Since the patient's prior examinations, there has been the interval development of lymphadenopathy throughout the mediastinum and both hilar regions that is suspicious for metastatic neoplastic lymphadenopathy in the chest.
2. There do not appear to be signs of pulmonary metastatic foci.
3. No sign of acute pulmonary disease. Mild interstitial scarring of the lungs.
4. No sign of a pleural effusion.
5. Right jugular Infuse-a-Port catheter coursing to the SVC.
6. Atherosclerosis of the thoracic aorta and coronary arteries.

CT abdomen impression:

1. Since the patient's prior examinations, there has been the interval development of low-density lesions in both lobes of the liver suspicious for metastatic disease.
2. Since the patient's prior examinations, there is been the interval development of lymphadenopathy throughout the small bowel mesentery and in the periaortic and pericaaval retroperitoneum suspicious for

[page 19 of 25]
neoplastic lymphadenopathy.

3. Nonobstructing small calculus lower pole right kidney.

4. Status post right colectomy. No signs of bowel obstruction or perforation.

5. Atherosclerosis of the abdominal aorta with infrarenal abdominal aortic aneurysm measuring 3 cm in size. Aneurysmal dilatation of the common iliac arteries as above.

CT pelvis impression:

1. No metastatic disease identified in the pelvis.

2. No acute process identified in the pelvis.

3. Mild enlargement of the prostate gland.

4. Suspect a small right inguinal hernia defect containing only a small amount of herniated fat.

[page 20 of 25]
IMAGING SERVICES

Exam Date/Time:	+630	Phone #	MRN
Sex:	Male		
Pt. Class:	Outpatient	Accession #:	Performing Department:
Primary Care Provider:			

Final - CT CHEST ABDOMEN PELVIS W CONT

Reason for Exam:

Diagnosis: Cecum cancer

INTERPRETATION

Exam: CT CHEST ABDOMEN PELVIS W CONT

Date/Time of Exam: +630

Reason For Exam: Cecum cancer. Malignant neoplasm of the colon. Post treatment follow-up. Repeat staging and reassessment for metastatic disease. Assessment for response to therapy.

Helical axial images of the chest, abdomen, and pelvis were obtained during IV administration of 125 mL Optiray 240. The patient ingested oral contrast for the exam. Sagittal and coronal reformats generated. Comparison made with the examination of and

Findings:

+281

+480

Lung window images demonstrate the lungs to be clear of acute infiltrates. Mild interstitial scarring is present in the inferior lungs near the lung bases. Old granulomatous calcifications are present in both lung bases. No focal pulmonary mass is identified. No sign of a pleural effusion or pneumothorax.

Mediastinal window images demonstrate a right jugular Infuse-a-Port catheter coursing to the SVC. Since the examinations of and there has been development of enlargement of mediastinal lymph nodes located in the aortopulmonary window region, pretracheal region, precarinal region, subcarinal region, and both hilar regions, especially in the right pulmonary hilus. The findings are suspicious for developing tumoral adenopathy in the mediastinum. The thoracic aorta is mildly ectatic and calcified without segmental aneurysm or dissection. The pulmonary arterial segments appear normal in caliber and enhance. The heart is normal in size and shape. No pericardial mass or effusion. There are coronary artery calcifications. No axillary adenopathy.

Narrow liver window images demonstrate hypodense lesions in the superior right lobe of the liver, medial segment of the left lobe of

+281

[page 21 of 25]
the liver, and very inferior posterior tip of the right lobe of the liver suspicious for hepatic metastatic disease. This appears to be new. The spleen is normal in size and shape. The pancreas is unremarkable. The right adrenal gland has normal appearance. There is nodular thickening of the limbs of the left adrenal gland. This could be related to very early metastatic disease in the left adrenal gland. No focal mass lesions are identified in the kidneys. No signs of hydronephrosis. There is a punctate nonobstructing calculus in the lower pole infundibulum of the right kidney. Lymphadenopathy is developing in the periaortic and pericaval region of the retroperitoneum. Additional lymphadenopathy is seen in the root of the small bowel mesentery. These findings appear to be new. There are no signs of abnormal distention of the stomach or bowel. There appear to be postoperative changes of right hemicolectomy with ileocolic anastomosis over the anterior mid abdomen at the mid transverse colon. No anterior abdominal wall hernia defects.

There is atherosclerotic calcification throughout the abdominal aorta and iliac arteries. The infrarenal aortic segment shows mild aneurysmal dilatation to a maximum diameter of 3 cm. There is diffuse aneurysmal dilatation of the left common iliac artery to a diameter of 2 cm. The right common iliac artery is ectatic measuring 1.7 cm. No retroperitoneal hematoma.

Scans continuing into the pelvis demonstrate grossly normal features of urinary bladder. The seminal vesicles are unremarkable. There is mild generalized enlargement of the prostate gland mildly impressing upon the base of the urinary bladder. No discrete pelvic mass. No pelvic lymphadenopathy. No pelvic fluid collections. The pelvic bowel is without signs of inflammation. There is a small right inguinal hernia defect containing only fat.

Bone window images reveal no lytic or blastic destructive changes in the visualized skeletal structures. Degenerative arthritic changes are present throughout the thoracolumbar spine.

IMPRESSION

CT chest impression:

1. Since the patient's prior examinations, there has been the interval development of lymphadenopathy throughout the mediastinum and both hilar regions that is suspicious for metastatic neoplastic lymphadenopathy in the chest.
2. There do not appear to be signs of pulmonary metastatic foci.
3. No sign of acute pulmonary disease. Mild interstitial scarring of the lungs.
4. No sign of a pleural effusion.
5. Right jugular Infuse-a-Port catheter coursing to the SVC.
6. Atherosclerosis of the thoracic aorta and coronary arteries.

CT abdomen impression:

1. Since the patient's prior examinations, there has been the interval development of low-density lesions in both lobes of the liver suspicious for metastatic disease.
2. Since the patient's prior examinations, there is been the interval development of lymphadenopathy throughout the small bowel mesentery and in the periaortic and pericaval retroperitoneum suspicious for

[page 22 of 25]
neoplastic lymphadenopathy.

3. Nonobstructing small calculus lower pole right kidney.

4. Status post right colectomy. No signs of bowel obstruction or perforation.

5. Atherosclerosis of the abdominal aorta with infrarenal abdominal aortic aneurysm measuring 3 cm in size. Aneurysmal dilatation of the common iliac arteries as above.

CT pelvis impression:

1. No metastatic disease identified in the pelvis.

2. No acute process identified in the pelvis.

3. Mild enlargement of the prostate gland.

4. Suspect a small right inguinal hernia defect containing only a small amount of herniated fat.

[page 23 of 25]
IMAGING SERVICES

Exam Date/Time:	+736	Referring Physician:	MRN:
Sex:	Male		
Accession #:			
Pt. Class:	Outpatient		
Primary Care Provider:			

Final - CT CHEST ABDOMEN PELVIS W CONT

Reason for Exam:

Diagnosis: Cecum cancer

INTERPRETATION

Exam: CT CHEST ABDOMEN PELVIS W CONT

Date/Time of Exam: +736

Reason For Exam: Cecum cancer. Malignant neoplasm of the colon. Posttreatment follow-up and reassessment restaging for metastatic disease.

Helical axial images of the chest, abdomen, and pelvis were obtained during IV administration of 70 mL Isovue-300. The patient ingested oral contrast for the exam. Sagittal and coronal reformats generated. Comparison made with the examination of +630

Findings: Lung window images demonstrate the trachea and bronchi to be patent. A few scattered calcified old granulomatous nodules are present in both lungs. No suspicious pulmonary nodule or mass lesion is seen. No acute pulmonary infiltrate is seen. No sign of a pleural effusion or pneumothorax.

Mediastinal window images demonstrate mildly enlarged lymph nodes in the right paratracheal region, pretracheal region, aortopulmonary window region, anterior precarinal region, both hilar regions, and subcarinal region. All the lymph nodes have decreased in size though compared to the prior examination. These have not completely resumed normal caliber. No new lymphadenopathy or new mediastinal mass. There is atherosclerotic ectasia and calcification of the thoracic aorta. Calcifications are present in the coronary arteries. The heart is normal in size and shape. No pericardial effusion. No axillary lymphadenopathy.

+630 Multiple small low-density lesions are seen scattered throughout both lobes of the liver. These show very slight decrease in size compared to +630. No new lesions are appreciated in the liver. The spleen is normal in size and shape with normal features. The pancreas is unremarkable. The right adrenal gland appears normal. There are some mild nodular thickening of the limbs of the left adrenal gland this

[page 24 of 25]
appears less pronounced than on the prior examination. No focal lesions are identified in the kidneys. Lymphadenopathy previously identified at the root of the mesentery and in the periaortic and pericaval retroperitoneum have regressed considerably. Small shotty appearing lymph nodes remain in the root of the small bowel mesentery and adjacent to the aorta and vena cava. No signs of abnormal distention of the stomach or bowel. No free air. No ascites. There is atherosclerotic calcification of the abdominal aorta and iliac arteries. There is aneurysmal dilatation of the infrarenal aortic segment with maximum diameter of 3 cm.

Scans continuing into the pelvis demonstrate grossly normal features of the urinary bladder, seminal vesicles, and prostate gland. No focal pelvic mass. No signs of pelvic lymphadenopathy. No pelvic fluid collections.

Bone window images reveal new sclerotic changes in the left half of the T10 vertebral body extending into the pedicle and left transverse process. No other focal lytic or sclerotic areas are seen suspicious for additional sites of osseous metastatic disease.

IMPRESSION

+630

CT chest impression:

1. Since the prior examination of [REDACTED] there appears to have been a favorable response to therapy with decreased caliber lymphadenopathy throughout the mediastinum and hilar regions of the chest. Findings compatible with regressing metastatic disease in these lymph node segments. The lymph nodes have not yet completely regressed. No new lymphadenopathy identified in the chest.
2. No signs of pulmonary metastatic disease.
3. No sign of acute pulmonary disease, CHF, pleural effusion, or pneumothorax.
4. Atherosclerosis of the thoracic aorta and coronary arteries.

CT abdomen impression:

1. Multiple small low-density metastatic lesions identified in both lobes of the liver that have minimally regressed at each site compared to the exam of [REDACTED]. No new or progressive lesions identified in the liver. +630
2. Shotty appearing lymph nodes in the mesentery of the bowel and retroperitoneum that have shown marked regression in caliber compared to [REDACTED] suggesting favorable response to therapy. Only tiny shotty appearing lymph nodes are now seen in the mesentery and retroperitoneum. No signs of progressive metastatic disease in the abdomen.
3. Atherosclerosis of the aorta and iliac arteries. There is a 3 cm infrarenal abdominal aortic aneurysm. This is unchanged.

CT pelvis impression:

1. No mass or adenopathy identified in the soft tissues of the pelvis.
2. There is note of interval development of sclerotic bony change in the T10 vertebral body extending into the left pedicle and left transverse process. The findings are new and raise concern of possible developing metastatic disease in the T10 vertebral segment. No associated pathologic fracture. No obvious signs of extension into the spinal canal. No exophytic paraspinal mass extension.

[page 25 of 25]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 63fc0f7e-7cdc-4a50-bea0-5d983c490b16 (ER0404 ER-B0CR Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).